Surgical pathology report (de-identified scan), TCGA case TCGA-3U-A98I, project TCGA-MESO (Mesothelioma), tissue source site University of Chicago, specimen TCGA-3U-A98I-01A (Primary Tumor).

[page 1 of 4]
Sample #

Gender: Male

DOB:

Race: White

Report Date:

Tissue Procurement Date:

ICD-O-3
Mesothelioma, biphasic malignant
9653/3
Site: @ Pleura NOS C38.4
QW3/2/14

Pathology Report:

Surgical Pathology Report

* Amended *

FINAL PATHOLOGIC DIAGNOSIS

A. Left pleura, pleurectomy:

- Malignant mesothelioma, biphasic type, 90% epithelioid (30% tubular, 30% micropapillary, 20% acinar, 20% solid) and 10% sarcomatoid, see parameters

B. # 5 lymph node, biopsy:

- One lymph node, extensively replaced by metastatic mesothelioma (epithelioid) with extracapsular involvement (1/1), see comment

C. 10L lymph node, biopsy:

- One lymph node, positive for metastatic mesothelioma (epithelioid) (1/1), see comment

D. # 6 lymph node, biopsy:

- Two lymph nodes, positive for metastatic mesothelioma (epithelioid) in lymph node parenchyma and lymphatic spaces (2/2), see comment

E. Left chest wall lymph node, biopsy:

- One lymph node, positive for metastatic mesothelioma (epithelioid) (1/1), see comment

Thoracic Mesothelioma Pathologic Parameters

Pleura/Pericardium, Resection

MACROSCOPIC

Specimen Type: Pleural resection with portion of pericardium and diaphragm

Tumor Site: Left pleura

Tumor Configuration and Size: Diffuse, maximum thickness: 1.3 cm

[page 2 of 4]
MICROSCOPIC

Histologic Type: Biphasic mesothelioma, 90% epithelioid (30% tubular, 30% micropapillary, 20% acinar, 20% solid) and 10% sarcomatoid

Tumor Extension

Confluent visceral pleural tumor

Into but not through diaphragm

Into lung parenchyma

Into mediastinal fat

Into and through the pericardium

Venous/Lymphatic Invasion: Present

Margins: Cannot be assessed

Additional Pathologic Findings: None identified

*Pathologic Staging (pTNM): pT4, N3

Primary Tumor (pT): pT4:

Tumor (locally advanced technically unresectable) involves any of the ipsilateral pleural surfaces, with at least 1 of the following: diffuse or multifocal invasion of soft tissues of the chest wall, any involvement of rib, invasion through the diaphragm to the peritoneum, invasion of any mediastinal organ(s), direct extension to the contralateral pleura, invasion into the spine, extension to the internal surface of the pericardium, pericardial effusion with positive cytology, invasion of the myocardium.

Regional Lymph Nodes (pN): pN3:

Metastases in the contralateral mediastinal, internal mammary, or hilar lymph node(s) and/or the ipsilateral or contralateral supraclavicular or scalene lymph node(s)

Specify: Number examined: 5

Number involved: 5

See Comment#2.

*Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for pleural mesothelioma of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

#1. Majority of the lymph node metastases are epithelioid and have micropapillary and solid architecture.

#2. Per Dr. [], "the chest wall lymph node from Part E is posterior near the brachial plexus, making it a positive N3 lymph node".

xxxx

[] M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] M.D.

Electronically Signed Out by [], M.D.

[page 3 of 4]
AMENDMENTS

Amended: x/x/ []

Reason: pathologic parameters modified

Staging modified-See Parameters for Regional Lymph nodes

Previous Signout Date: x/x

Clinical History:

This is a year-old male with biopsy diagnosis of malignant mesothelioma.

Specimens Received:

A: Left pleura

B: # 5 lymph node

C: 10L lymph node

D: # 6 lymph node

E: Left chest wall lymph node

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "left pleura". Received fresh is a pleurectomy specimen, measuring 1117.4 gram, approximately 1200 cc. It consists of multiple pieces ranging from 1 x 0.8 x 0.3 cm-25 x 12 x 4 cm in size. The largest piece is oriented by a stitch designating diaphragm (measuring 15 x 15 cm), which is inked green. There is a 9.5 x 5.5 cm area of membranous tissue on the second largest piece which is oriented by the surgeon as pericardium, which is inked blue. There is 12 x 7 x 4 cm portion of adipose tissue closely associated with the pericardium in the pleura. The specimen demonstrates diffuse nodularity on the surface, ranging from 0.3-1.3 cm in size. There is one 9 x 4.5 cm area of possible lung tissue attached to one of the pieces. The specimen is serially sectioned white, firm lobulated tumor involving every piece. The visceral and parietal pleura are thickened up to 2.0 cm and fused. The pericardium and diaphragm surface is smooth and glistening. The tumor is grossly invading the surrounding adipose tissue. Gross pictures of the 2 largest pieces are taken.

Representative sections are taken as follows:

A1-2: Sections of the tumor with possible lung tissue

A3-5: Sections of the tumor with pericardium and adipose tissue

A6-8: Sections of the tumor with diaphragm

A9-15: Representative sections of the tumor

B. The second container is additionally identified as, "#5 lymph node".

Received fresh and placed in formalin is a 1 cm nodule which is bisected and

[page 4 of 4]
entirely submitted as B1.

C. The third container is additionally identified as, "10L LYMPH node".
Received fresh and placed in formalin is a 1.5 cm nodule which is bisected and entirely submitted as C1.

D. The fourth container is additionally identified as, "#6 lymph node".
Received fresh and placed in formalin are two 1.5 cm nodules, which are bisected and submitted in D1 and D2 respectively.

E. The fifth container is additionally identified as, "left chest wall lymph node". Received fresh in the placed in formalin is a 0.6 cm nodule which is bisected and entirely submitted as E1.

xx

☐ M.D., Ph.D.

mw 1/8/14
mw *1/16/13*

Source: NCI Genomic Data Commons file b5734adb-289d-42d3-9f0a-919dca51b057 (TCGA-3U-A98I.034C160F-20F8-42D2-A1EE-DF8ED1B569B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).